Somatic mutation profile of tumor specimen TCGA-AP-A0LG-01A (aliquot TCGA-AP-A0LG-01A-11W-A062-09) from TCGA case TCGA-AP-A0LG, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IA; Tumor grade: G3; Age at diagnosis: 54.9 years (20,047 days).
Specimen TCGA-AP-A0LG-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33280ade-0e33-4a1f-9f43-799804850c06.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AP-A0LG-10A (Blood Derived Normal), aliquot TCGA-AP-A0LG-10A-01W-A062-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/77f1d6d9-1ecd-4078-944c-ddc05703d9ae

The open-access MAF lists 529 somatic variants for this specimen: 396 protein-altering or splice-affecting, 117 silent, 16 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 258, Silent 117, Frame Shift Del 83, Frame Shift Ins 21, Nonsense Mutation 19, Splice Region 6, RNA 5, In Frame Del 5, 3'UTR 5, Splice Site 3, 3'Flank 2, 5'Flank 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATP8B1 | c.614dup p.N205Kfs*2 | Frame Shift Ins (INS) | VAF 29/79 reads (37%) | catalogued as rs761784230; ClinVar: pathogenic; called by mutect2, varscan2
- CHD7 | c.8962dup p.D2988Gfs*2 | Frame Shift Ins (INS) | VAF 28/51 reads (55%) | catalogued as rs771806027, CI084262; ClinVar: uncertain significance / pathogenic; called by mutect2, varscan2
- CHEK2 | c.802dup p.T268Nfs*20 (on ENST00000382580 / NM_001005735.2; = p.T225Nfs*20 on NM_007194.4) | Frame Shift Ins (INS) | VAF 13/29 reads (45%) | catalogued as rs1342011335; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- CTNNB1 | c.109T>G p.S37A | Missense Mutation (SNP) | VAF 47/88 reads (53%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913228, COSV62688488, COSV62688537, COSV62706597; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FBN1 | c.660del p.C221Vfs*109 | Frame Shift Del (DEL) | VAF 23/104 reads (22%) | catalogued as rs727505269; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.183A>C p.Q61H | Missense Mutation (SNP) | VAF 41/93 reads (44%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.121); catalogued as rs17851045, COSV55498802, COSV55499223, COSV55811221; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- MEIS2 | c.825dup p.R276Tfs*54 (on ENST00000561208 / NM_170675.5; = p.R263Tfs*54 on NM_002399.3) | Frame Shift Ins (INS) | VAF 59/275 reads (21%) | catalogued as rs1555456994; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- PIK3CA | c.3140A>T p.H1047L | Missense Mutation (SNP) | VAF 81/178 reads (46%) | hotspot (GDC flag); SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.97_99del p.I33del | In Frame Del (DEL) | VAF 73/181 reads (40%) | catalogued as rs1554893765; ClinVar: uncertain significance / likely pathogenic; called by pindel, varscan2
- PTEN | c.968dup p.N323Kfs*2 | Frame Shift Ins (INS) | VAF 144/426 reads (34%) | catalogued as rs121913291; ClinVar: likely pathogenic / pathogenic; called by pindel, varscan2
- AARS1 | c.1705C>T p.R569* | Nonsense Mutation (SNP) | VAF 20/43 reads (47%) | catalogued as rs747434741, COSV55748340; called by muse, mutect2, varscan2
- ABCA13 | c.10211T>C p.L3404P | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.648); catalogued as rs1232689830, COSV71291490; called by muse, mutect2, varscan2
- ABCB6 | c.953del p.G318Vfs*9 | Frame Shift Del (DEL) | VAF 16/39 reads (41%) | catalogued as rs777439793; called by mutect2, pindel, varscan2
- ABCC8 | c.1766C>T p.P589L | Missense Mutation (SNP) | VAF 74/169 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100217012, COSV56851438; called by muse, mutect2, varscan2
- ACSS2 | c.806del p.P269Qfs*69 | Frame Shift Del (DEL) | VAF 13/41 reads (32%) | catalogued as rs745681981, COSV53623223; called by mutect2, varscan2
- ACSS3 | c.902G>A p.G301D | Missense Mutation (SNP) | VAF 27/138 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239532528, COSV54096233, COSV54104713; called by muse, mutect2, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 32/227 reads (14%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAM15 | c.2558C>A p.P853Q (on ENST00000356955 / NM_207197.3; = p.P804Q on NM_003815.5) | Missense Mutation (SNP) | VAF 4/13 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV55128558; called by muse, mutect2
- ADAM9 | c.412G>T p.G138* | Nonsense Mutation (SNP) | VAF 21/158 reads (13%) | catalogued as COSV65946779; called by muse, mutect2, varscan2
- ADAMTSL1 | c.677-1G>T p.X226_splice | Splice Site (SNP) | VAF 66/162 reads (41%) | catalogued as COSV52820085, COSV99442612; called by muse, mutect2, varscan2
- ADD3 | c.2102del p.K701Rfs*8 (on ENST00000356080 / NM_001320591.2; = p.K669Rfs*8 on NM_001121.4) | Frame Shift Del (DEL) | VAF 171/226 reads (76%) | catalogued as rs760140619; called by mutect2, varscan2
- ADGRB2 | c.1676dup p.N560Efs*32 | Frame Shift Ins (INS) | VAF 6/49 reads (12%) | catalogued as rs764766993; called by pindel, varscan2
- AMD1 | c.670A>G p.N224D | Missense Mutation (SNP) | VAF 106/262 reads (40%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as COSV64387813; called by muse, mutect2, varscan2
- ANKFY1 | c.2072del p.P691Rfs*61 (on ENST00000341657 / NM_001330063.2; = p.P692Rfs*61 on NM_016376.5) | Frame Shift Del (DEL) | VAF 114/312 reads (37%) | catalogued as COSV58920130; called by mutect2, pindel, varscan2
- ANKRD52 | c.1622C>T p.A541V | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.893); catalogued as COSV57285902; called by muse, mutect2
- ANPEP | c.2124G>A p.M708I | Missense Mutation (SNP) | VAF 19/182 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.511); catalogued as COSV55593167; called by muse, mutect2
- APBB1 | c.1503+1G>A p.X501_splice | Splice Site (SNP) | VAF 32/102 reads (31%) | catalogued as COSV54978380; called by muse, mutect2, varscan2
- APOA1 | c.146G>A p.S49N | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.06); PolyPhen benign (0.32); catalogued as rs755026583, COSV52636195; called by muse, mutect2, varscan2
- APOBEC4 | c.975G>A p.M325I | Missense Mutation (SNP) | VAF 124/268 reads (46%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs576075334, COSV58018105; called by muse, mutect2, varscan2
- APPL1 | c.460del p.R154Efs*6 | Frame Shift Del (DEL) | VAF 18/62 reads (29%) | catalogued as rs749401724; called by mutect2, varscan2
- ARHGAP10 | c.872G>A p.C291Y | Missense Mutation (SNP) | VAF 93/228 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV60602833; called by muse, mutect2, varscan2
- ARHGEF10 | c.331A>G p.M111V (on ENST00000398564; = p.M87V on NM_014629.4) | Missense Mutation (SNP) | VAF 43/105 reads (41%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0); catalogued as COSV50661647; called by muse, mutect2, varscan2
- ARHGEF40 | c.3242G>A p.R1081Q | Missense Mutation (SNP) | VAF 5/11 reads (45%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.766); catalogued as rs61750464; called by muse, mutect2, varscan2
- ARID1A | c.2348del p.T783Kfs*50 | Frame Shift Del (DEL) | VAF 48/133 reads (36%) | catalogued as COSV61377227; called by mutect2, pindel, varscan2
- ARSJ | c.1736del p.K579Rfs*30 | Frame Shift Del (DEL) | VAF 42/94 reads (45%) | catalogued as rs753865255; called by mutect2, varscan2
- ASPRV1 | c.4G>T p.G2W | Missense Mutation (SNP) | VAF 46/110 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.87); catalogued as COSV57228669; called by muse, mutect2, varscan2
- ATG2B | c.3120del p.K1040Nfs*2 | Frame Shift Del (DEL) | VAF 61/147 reads (41%) | catalogued as rs771531141; called by mutect2, varscan2
- ATP1A4 | c.1940C>T p.A647V | Missense Mutation (SNP) | VAF 50/199 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV63627425; called by muse, mutect2
- ATP2A2 | c.1910G>A p.R637H | Missense Mutation (SNP) | VAF 49/112 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.73); catalogued as rs753907244, COSV57875857; called by muse, mutect2, varscan2
- ATP8B4 | c.967G>A p.G323R | Missense Mutation (SNP) | VAF 148/354 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as rs762729078, COSV52719814; called by muse, mutect2, varscan2
- AVPR2 | c.415C>T p.R139C | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs1224716948, CP984524, COSV61686595; called by muse, mutect2, varscan2
- BANP | c.616A>G p.T206A (on ENST00000286122; = p.T175A on NM_017869.4) | Missense Mutation (SNP) | VAF 20/54 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.977); catalogued as COSV53740178; called by muse, mutect2, varscan2
- BCHE | c.1027del p.T343Pfs*16 | Frame Shift Del (DEL) | VAF 43/127 reads (34%) | catalogued as CM025285, COSV52257903; called by mutect2, pindel, varscan2
- BLZF1 | c.426G>T p.Q142H | Missense Mutation (SNP) | VAF 81/215 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV61394297; called by muse, mutect2, varscan2
- BPIFB6 | c.1126G>A p.A376T | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated (0.47); PolyPhen benign (0.006); catalogued as rs1182679141, COSV62756010; called by muse, mutect2, varscan2
- BRD8 | c.2250-3del | Splice Region (DEL) | VAF 67/154 reads (44%) | catalogued as rs749043197; called by mutect2, varscan2
- BRSK1 | c.618del p.K206Nfs*38 | Frame Shift Del (DEL) | VAF 29/67 reads (43%) | catalogued as COSV58666488; called by mutect2, pindel, varscan2
- BRWD3 | c.4959A>T p.K1653N | Missense Mutation (SNP) | VAF 278/659 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.72); catalogued as COSV64751294; called by muse, mutect2, varscan2
- BTN3A1 | c.43C>T p.R15C | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT tolerated (0.18); PolyPhen benign (0.2); catalogued as rs374921833, COSV50024493; called by muse, mutect2, varscan2
- C11orf87 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs1345358540, COSV59357676; called by muse, mutect2, varscan2
- C2orf15 | c.274T>C p.*92Rext*16 | Nonstop Mutation (SNP) | VAF 21/114 reads (18%) | catalogued as rs778151271, COSV56782183; called by muse, mutect2, varscan2
- C2orf16 | c.4283T>C p.L1428S | Missense Mutation (SNP) | VAF 72/163 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.255); catalogued as COSV62677052; called by muse, mutect2, varscan2
- C8A | c.1523C>T p.P508L | Missense Mutation (SNP) | VAF 36/78 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.911); catalogued as rs139907890; called by muse, mutect2
- CACNA1E | c.5186T>A p.L1729Q | Missense Mutation (SNP) | VAF 12/235 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62406604; called by muse, mutect2
- CACNA1E | c.5730G>T p.E1910D | Missense Mutation (SNP) | VAF 49/477 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.05); catalogued as COSV100701401, COSV62406610; called by muse, mutect2, varscan2
- CACNA1G | c.1135A>C p.I379L | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.669); catalogued as rs1323353704, COSV61732575; called by muse, mutect2, varscan2
- CACNA1G | c.2663G>A p.G888D | Missense Mutation (SNP) | VAF 14/91 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61732592; called by muse, mutect2, varscan2
- CAD | c.1754C>G p.T585S | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as COSV53029342; called by muse, mutect2, varscan2
- CASP8 | c.848C>T p.P283L (on ENST00000432109 / NM_033355.3; = p.P300L on NM_001228.4) | Missense Mutation (SNP) | VAF 89/182 reads (49%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV51855233; called by muse, mutect2
- CBLB | c.1621G>T p.D541Y | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.529); catalogued as COSV51431684; called by muse, mutect2
- CCDC18 | c.774del p.V259Wfs*15 | Frame Shift Del (DEL) | VAF 38/70 reads (54%) | catalogued as rs746565576, COSV58142470; called by mutect2, varscan2
- CCND2 | c.783C>G p.Y261* | Nonsense Mutation (SNP) | VAF 66/130 reads (51%) | catalogued as COSV54224624, COSV99714177; called by muse, mutect2, varscan2
- CD300LF | c.472C>T p.L158F | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1227187872, COSV56897878; called by muse, mutect2, varscan2
- CD9 | c.199G>A p.G67S | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1323773895, COSV50531035; called by muse, mutect2
- CDH23 | c.7519C>T p.P2507S | Missense Mutation (SNP) | VAF 39/81 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV56476974; called by muse, mutect2, varscan2
- CEP85 | c.674C>T p.A225V | Missense Mutation (SNP) | VAF 24/146 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.04); catalogued as COSV53331043; called by muse, mutect2
- CES5A | c.1059G>A p.K353= | Splice Region (SNP) | VAF 81/176 reads (46%) | catalogued as COSV51868530; called by muse, mutect2, varscan2
- CHRNB4 | c.1426G>T p.G476W | Missense Mutation (SNP) | VAF 56/165 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55717131; called by muse, mutect2, varscan2
- CHST5 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.474); catalogued as rs774433525, COSV60336852; called by muse, mutect2, varscan2
- CIART | c.913C>A p.H305N | Missense Mutation (SNP) | VAF 199/642 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.369); catalogued as COSV51745212; called by muse, mutect2, varscan2
- CIC | c.568C>T p.R190C | Missense Mutation (SNP) | VAF 29/73 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.858); catalogued as rs767502801, COSV50627470; called by muse, mutect2, varscan2
- CLPTM1 | c.1162C>A p.L388M | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.672); catalogued as COSV61612468; called by muse, mutect2, varscan2
- CMYA5 | c.5965G>A p.E1989K | Missense Mutation (SNP) | VAF 91/214 reads (43%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.001); catalogued as COSV71407760; called by muse, mutect2, varscan2
- CNBD1 | c.207A>T p.Q69H | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as COSV72917280; called by muse, mutect2, varscan2
- CNTNAP5 | c.251A>C p.N84T | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.412); catalogued as COSV70477518, COSV70498035; called by muse, mutect2
- COL7A1 | c.8474G>A p.G2825D | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1319107811, COSV56476868; called by muse, mutect2, varscan2
- COL8A1 | c.2137C>T p.R713W | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs1226770157, COSV53738510; called by muse, mutect2, varscan2
- COMMD10 | c.244G>A p.A82T | Missense Mutation (SNP) | VAF 6/148 reads (4%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.973); catalogued as COSV57238895; called by muse, mutect2
- COQ4 | c.640C>A p.L214M | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55957600; called by muse, mutect2, varscan2
- CPNE3 | c.778del p.S260Afs*10 | Frame Shift Del (DEL) | VAF 96/260 reads (37%) | catalogued as rs761955273; called by mutect2, pindel, varscan2
- CPQ | c.59G>T p.G20V | Missense Mutation (SNP) | VAF 157/397 reads (40%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); catalogued as rs747054913, COSV55153229; called by muse, mutect2, varscan2
- CRYGA | c.350G>A p.R117H | Missense Mutation (SNP) | VAF 58/109 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs199794131, COSV58017838; called by muse, mutect2, varscan2
- CUL9 | c.3305G>T p.R1102L | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.074); catalogued as COSV52731515; called by muse, mutect2, varscan2
- CYFIP1 | c.3074C>T p.A1025V | Missense Mutation (SNP) | VAF 32/175 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs138063523; called by muse, mutect2, varscan2
- DAO | c.82C>A p.Q28K | Missense Mutation (SNP) | VAF 65/103 reads (63%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV57321644, COSV57323645; called by muse, mutect2, varscan2
- DAPL1 | c.127del p.T43Qfs*21 | Frame Shift Del (DEL) | VAF 19/46 reads (41%) | catalogued as rs763165810; called by mutect2, pindel, varscan2
- DDIT4L | c.254C>T p.T85I | Missense Mutation (SNP) | VAF 55/124 reads (44%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.815); catalogued as rs1473523751, COSV56767775; called by muse, mutect2, varscan2
- DDX60L | c.770C>A p.S257* | Nonsense Mutation (SNP) | VAF 13/58 reads (22%) | catalogued as COSV52709792, COSV52717607; called by muse, mutect2, varscan2
- DEFB118 | c.359A>G p.H120R | Missense Mutation (SNP) | VAF 92/189 reads (49%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.146); catalogued as rs1007068227, COSV53620967; called by muse, mutect2, varscan2
- DENND1C | c.1342G>A p.V448I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); catalogued as rs373788641; called by muse, mutect2, varscan2
- DENND2A | c.2926C>T p.R976* | Nonsense Mutation (SNP) | VAF 30/69 reads (43%) | catalogued as COSV52055065; called by muse, mutect2, varscan2
- DGKG | c.727C>T p.Q243* | Nonsense Mutation (SNP) | VAF 121/307 reads (39%) | catalogued as COSV53968726; called by muse, mutect2, varscan2
- DMP1 | c.229G>T p.G77C | Missense Mutation (SNP) | VAF 67/136 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV56821364; called by muse, mutect2, varscan2
- DNAH10 | c.4775G>A p.C1592Y (on ENST00000409039; = p.C1531Y on NM_207437.3) | Missense Mutation (SNP) | VAF 52/107 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1414464870, COSV68997420; called by muse, mutect2, varscan2
- DNAH11 | c.8231G>A p.R2744H | Missense Mutation (SNP) | VAF 112/259 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as rs566881130, COSV60955084; called by muse, mutect2, varscan2
- DNAH11 | c.10241C>T p.T3414M | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.392); catalogued as rs779964310, COSV60937035; called by muse, mutect2
- DNAH17 | c.11038A>G p.K3680E | Missense Mutation (SNP) | VAF 7/15 reads (47%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs758965425, COSV67758457; called by muse, mutect2, varscan2
- DNAH2 | c.9381G>A p.M3127I | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV66722713; called by muse, mutect2, varscan2
- DNAI2 | c.1310T>A p.F437Y | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs761280652, COSV56760868; called by muse, mutect2, varscan2
- DPF2 | c.466C>T p.R156W | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52890488; called by muse, mutect2, varscan2
- DUS4L-BCAP29 | c.522G>T p.K174N | Missense Mutation (SNP) | VAF 34/88 reads (39%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.723); catalogued as COSV50052279; called by muse, mutect2, varscan2
- EPN1 | c.833del p.G278Afs*164 (on ENST00000270460 / NM_001321263.1; = p.G253Afs*163 on NM_013333.3) | Frame Shift Del (DEL) | VAF 17/48 reads (35%) | catalogued as rs755604942; called by mutect2, pindel, varscan2
- ERAS | c.289G>A p.A97T | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV54432715; called by muse, mutect2, varscan2
- ESD | c.558dup p.A187Sfs*3 | Frame Shift Ins (INS) | VAF 76/206 reads (37%) | catalogued as rs757002477; called by mutect2, pindel, varscan2
- EVPL | c.4606C>T p.R1536W | Missense Mutation (SNP) | VAF 47/98 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.045); catalogued as rs768199812, COSV56908621; called by muse, mutect2, varscan2
- FAHD2A | c.842del p.P281Qfs*26 | Frame Shift Del (DEL) | VAF 23/65 reads (35%) | catalogued as rs766589051; called by mutect2, pindel, varscan2
- FBXL7 | c.1162G>T p.G388C | Missense Mutation (SNP) | VAF 34/58 reads (59%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV61642183; called by muse, mutect2, varscan2
- FBXW9 | c.853G>T p.D285Y (on ENST00000587955; = p.A295S on NM_032301.3) | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.466); catalogued as COSV66710191; called by muse, mutect2, varscan2
- FCER1G | c.115C>A p.L39I | Missense Mutation (SNP) | VAF 38/420 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV57155461; called by muse, mutect2
- FETUB | c.437del p.K146Rfs*4 | Frame Shift Del (DEL) | VAF 91/301 reads (30%) | catalogued as rs748969702; called by mutect2, varscan2
- FLG | c.5879A>G p.H1960R | Missense Mutation (SNP) | VAF 142/312 reads (46%) | SIFT tolerated (0.24); PolyPhen benign (0.014); catalogued as COSV64244927; called by muse, mutect2
- FNDC4 | c.251G>A p.R84Q | Missense Mutation (SNP) | VAF 6/20 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.704); catalogued as COSV53022217; called by muse, mutect2
- FOXD4L5 | c.700G>T p.G234C | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV66240831; called by muse, mutect2, varscan2
- FPGS | c.1351G>A p.A451T | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs1333568632, COSV61228143; called by muse, mutect2, varscan2
- FSCN3 | c.853C>T p.R285C | Missense Mutation (SNP) | VAF 128/328 reads (39%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs148605578; called by muse, mutect2, varscan2
- FTCD | c.1492G>A p.V498M | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.801); catalogued as rs771799096, COSV52423288; called by muse, mutect2
- FZD3 | c.184A>G p.M62V | Missense Mutation (SNP) | VAF 46/107 reads (43%) | SIFT tolerated (0.72); PolyPhen benign (0.356); catalogued as rs61754565, COSV53536744; called by muse, mutect2, varscan2
- GCLC | c.180del p.V61Sfs*37 (on ENST00000643939; = p.V65Sfs*37 on NM_001498.4) | Frame Shift Del (DEL) | VAF 42/132 reads (32%) | catalogued as rs1269042612; called by mutect2, pindel, varscan2
- GCNA | c.169G>T p.G57C | Missense Mutation (SNP) | VAF 50/113 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); catalogued as COSV65467617; called by muse, mutect2, varscan2
- GFRA1 | c.128G>A p.S43N | Missense Mutation (SNP) | VAF 21/37 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1442919700, COSV62602649; called by muse, mutect2, varscan2
- GIPC2 | c.480T>G p.D160E | Missense Mutation (SNP) | VAF 123/266 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63379787; called by muse, mutect2, varscan2
- GLI4 | c.113G>T p.G38V | Missense Mutation (SNP) | VAF 17/35 reads (49%) | SIFT tolerated (0.21); PolyPhen benign (0.083); catalogued as COSV60681746, COSV60682413; called by muse, mutect2, varscan2
- GNAS | c.1732G>A p.G578R | Missense Mutation (SNP) | VAF 4/9 reads (44%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.001); catalogued as rs753954316, COSV58341032; called by muse, mutect2
- GOLGA2 | c.2929del p.Y977Tfs*9 | Frame Shift Del (DEL) | VAF 68/164 reads (41%) | catalogued as rs763679060; called by mutect2, varscan2
- GPAM | c.1885G>A p.E629K | Missense Mutation (SNP) | VAF 67/122 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV62081889; called by muse, mutect2, varscan2
- GPAM | c.1189C>T p.R397* | Nonsense Mutation (SNP) | VAF 15/231 reads (6%) | catalogued as rs769234596, COSV62081894; called by muse, mutect2
- GRB14 | c.1032G>A p.M344I | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.23); PolyPhen benign (0.009); catalogued as rs755185374, COSV55740563; called by muse, mutect2, varscan2
- GRWD1 | c.997A>G p.K333E | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.877); catalogued as COSV53519728; called by muse, mutect2
- HECA | c.374G>A p.C125Y | Missense Mutation (SNP) | VAF 49/177 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62770038; called by muse, mutect2, varscan2
- HSD3B1 | c.95T>A p.I32N | Missense Mutation (SNP) | VAF 160/359 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV52491496; called by muse, mutect2, varscan2
- HTT | c.3590C>T p.P1197L | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.45); catalogued as rs767004706, COSV61865643; called by muse, mutect2, varscan2
- HUWE1 | c.5669A>G p.N1890S | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT tolerated (0.62); PolyPhen benign (0.007); catalogued as COSV53355724; called by muse, mutect2, varscan2
- HYDIN | c.2701G>A p.G901R | Missense Mutation (SNP) | VAF 28/52 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs761094125, COSV58564640; called by mutect2, varscan2
- IBTK | c.3638del p.K1213Sfs*50 | Frame Shift Del (DEL) | VAF 50/122 reads (41%) | catalogued as rs757667533; called by mutect2, pindel, varscan2
- IFT122 | c.1753G>A p.V585M (on ENST00000348417 / NM_052989.3; = p.V526M on NM_018262.4) | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV56205635; called by muse, mutect2, varscan2
- IGF2R | c.4500G>A p.W1500* | Nonsense Mutation (SNP) | VAF 59/139 reads (42%) | catalogued as COSV63630943; called by muse, mutect2, varscan2
- IGFN1 | c.2762C>T p.A921V (on ENST00000295591 / NM_001367841.1; = p.A3378V on NM_001164586.2) | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1014263818, COSV55178643; called by muse, mutect2, varscan2
- IL16 | c.3547C>T p.R1183C (on ENST00000302987 / NM_172217.5; = p.R482C on NM_004513.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 50/146 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770059879, COSV57155041; called by muse, mutect2, varscan2
- IL17RE | c.782T>C p.F261S | Missense Mutation (SNP) | VAF 11/32 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV55969520; called by muse, mutect2, varscan2
- INTS6L | c.359del p.L120* | Frame Shift Del (DEL) | VAF 52/132 reads (39%) | catalogued as rs782242788; ClinVar: uncertain significance; called by mutect2, varscan2
- ISM2 | c.1489G>T p.D497Y | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0.02); PolyPhen benign (0.397); catalogued as COSV53636009; called by muse, mutect2, varscan2
- ITGAX | c.1649G>A p.R550Q | Missense Mutation (SNP) | VAF 58/122 reads (48%) | SIFT tolerated (0.54); PolyPhen benign (0.027); catalogued as rs201067451, COSV51648488; called by muse, mutect2, varscan2
- ITGB1 | c.1433A>G p.H478R | Missense Mutation (SNP) | VAF 117/248 reads (47%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.467); catalogued as rs1275098280, COSV56484291; called by muse, mutect2, varscan2
- JPH3 | c.901G>A p.G301S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1322374578, COSV52471144; called by muse, mutect2, varscan2
- KCNH2 | c.3229G>A p.A1077T | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs201382073, COSV51209634; ClinVar: uncertain significance; called by muse, mutect2
- KDM3B | c.2080A>G p.I694V | Missense Mutation (SNP) | VAF 44/116 reads (38%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.024); catalogued as rs781672306, COSV58693043; called by muse, mutect2, varscan2
- KIAA0232 | c.851G>A p.R284H | Missense Mutation (SNP) | VAF 56/134 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.817); catalogued as rs370763248; called by muse, mutect2, varscan2
- KIF2A | c.674G>A p.C225Y | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV66946147; called by muse, mutect2, varscan2
- KIR2DL4 | c.1076G>T p.S359I (on ENST00000396284; = p.S285I on NM_001080770.2) | Missense Mutation (SNP) | VAF 190/653 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.111); catalogued as COSV58493550; called by muse, mutect2, varscan2
- KLF12 | c.914G>T p.R305L | Missense Mutation (SNP) | VAF 52/120 reads (43%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.488); catalogued as COSV100888544, COSV66577155; called by muse, mutect2, varscan2
- KLF4 | c.1129G>T p.E377* | Nonsense Mutation (SNP) | VAF 16/60 reads (27%) | catalogued as COSV65929281; called by muse, mutect2, varscan2
- KMT2D | c.16283G>A p.G5428D | Missense Mutation (SNP) | VAF 110/257 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM111926, COSV56437105; called by muse, mutect2, varscan2
- KNOP1 | c.652del p.I218Sfs*41 | Frame Shift Del (DEL) | VAF 44/112 reads (39%) | catalogued as rs764099275; called by mutect2, varscan2
- LAMB1 | c.320G>A p.R107H | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.993); catalogued as COSV55967599; called by muse, mutect2, varscan2
- LAMB4 | c.975G>T p.Q325H | Missense Mutation (SNP) | VAF 54/118 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.353); catalogued as COSV52724917; called by muse, mutect2, varscan2
- LAMC3 | c.1339C>T p.R447C | Missense Mutation (SNP) | VAF 28/58 reads (48%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as rs777086759, COSV63090346; called by muse, mutect2, varscan2
- LARGE2 | c.586C>A p.R196S | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.657); catalogued as COSV57657053; called by muse, mutect2
- LARGE2 | c.1325G>A p.R442Q | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs775493980, COSV57657058; called by muse, mutect2, varscan2
- LAS1L | c.338T>C p.L113P | Missense Mutation (SNP) | VAF 178/386 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.838); catalogued as COSV56708259; called by muse, mutect2, varscan2
- LEO1 | c.1168G>A p.D390N | Missense Mutation (SNP) | VAF 76/178 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as COSV55176539, COSV55177197; called by muse, mutect2, varscan2
- LMAN1 | c.912del p.E305Rfs*22 | Frame Shift Del (DEL) | VAF 140/308 reads (45%) | catalogued as rs746845401, CD099553; called by mutect2, varscan2
- LPCAT3 | c.1117T>G p.W373G | Missense Mutation (SNP) | VAF 13/171 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54643057; called by muse, mutect2
- LRPAP1 | c.258G>T p.Q86H | Missense Mutation (SNP) | VAF 17/200 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.384); catalogued as COSV56347139; called by muse, mutect2
- LSMEM1 | c.222C>A p.S74R | Missense Mutation (SNP) | VAF 48/199 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.893); catalogued as rs544127044, COSV57196776; called by muse, mutect2, varscan2
- MAG | c.440C>T p.P147L | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.551); catalogued as COSV62701778; called by muse, mutect2, varscan2
- MAMSTR | c.485del p.P162Hfs*14 (on ENST00000318083 / NM_001130915.2; = p.P59Hfs*14 on NM_182574.2) | Frame Shift Del (DEL) | VAF 13/35 reads (37%) | catalogued as rs752869239; called by mutect2, varscan2
- MAP3K21 | c.1052C>T p.A351V | Missense Mutation (SNP) | VAF 30/199 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV64045617; called by muse, mutect2, varscan2
- MCM3AP | c.385C>T p.Q129* | Nonsense Mutation (SNP) | VAF 39/90 reads (43%) | catalogued as COSV52442659; called by muse, mutect2, varscan2
- MED24 | c.769A>G p.T257A | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.592); catalogued as COSV62419887; called by muse, mutect2, varscan2
- MFSD6 | c.107C>A p.P36H | Missense Mutation (SNP) | VAF 87/184 reads (47%) | SIFT tolerated (0.07); PolyPhen benign (0.042); catalogued as COSV55624000; called by muse, mutect2, varscan2
- MGAT2 | c.1061C>T p.T354I | Missense Mutation (SNP) | VAF 22/180 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV53566679; called by muse, mutect2, varscan2
- MINAR1 | c.2104del p.S702Afs*11 | Frame Shift Del (DEL) | VAF 34/272 reads (13%) | catalogued as rs748072217, COSV59581461; called by mutect2, varscan2
- MIPOL1 | c.114G>A p.M38I | Missense Mutation (SNP) | VAF 16/84 reads (19%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as COSV59388558; called by muse, mutect2, varscan2
- MKI67 | c.5324C>T p.T1775M | Missense Mutation (SNP) | VAF 104/353 reads (29%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.993); catalogued as rs372972364; called by muse, mutect2, varscan2
- MORC2 | c.2564del p.P855Lfs*27 (on ENST00000397641 / NM_001303256.3; = p.P793Lfs*27 on NM_014941.3) | Frame Shift Del (DEL) | VAF 29/75 reads (39%) | catalogued as COSV99310272; called by mutect2, pindel, varscan2
- MORC4 | c.481G>A p.A161T | Missense Mutation (SNP) | VAF 140/330 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV55244793; called by muse, mutect2, varscan2
- MPI | c.1054G>A p.V352I | Missense Mutation (SNP) | VAF 39/79 reads (49%) | SIFT tolerated (0.58); PolyPhen benign (0.05); catalogued as rs887001981, COSV60397224; called by muse, mutect2, varscan2
- MPPE1 | c.731_732insA p.V245Cfs*13 | Frame Shift Ins (INS) | VAF 14/46 reads (30%) | catalogued as COSV100013221; called by mutect2, pindel, varscan2
- MSH5 | c.860G>A p.R287H | Missense Mutation (SNP) | VAF 99/225 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746903566, COSV65210517; called by muse, mutect2, varscan2
- MTIF2 | c.634G>T p.G212C | Missense Mutation (SNP) | VAF 49/127 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55052804; called by muse, mutect2, varscan2
- MTMR6 | c.745A>G p.R249G | Missense Mutation (SNP) | VAF 30/70 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV67809024; called by muse, mutect2, varscan2
- MTMR7 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV51668412, COSV51670936; called by muse, mutect2, varscan2
- MYH1 | c.4406C>T p.A1469V | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.015); catalogued as COSV56849878; called by muse, mutect2, varscan2
- MYO10 | c.3667G>A p.G1223R | Missense Mutation (SNP) | VAF 32/197 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1434873123, COSV57016082, COSV57017061; called by muse, mutect2, varscan2
- MYO5C | c.593A>G p.N198S | Missense Mutation (SNP) | VAF 78/159 reads (49%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.773); catalogued as COSV55909402; called by muse, mutect2, varscan2
- MYOM1 | c.4654G>A p.D1552N | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0.02); PolyPhen benign (0.154); catalogued as rs759276149, COSV55289668; called by muse, mutect2, varscan2
- N6AMT1 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 9/166 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.005); catalogued as COSV58135199; called by muse, mutect2
- NAA60 | c.547G>A p.G183S | Missense Mutation (SNP) | VAF 23/49 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.764); catalogued as rs1357438915, COSV62655492; called by muse, mutect2, varscan2
- NAGS | c.1502_1504del p.F501del | In Frame Del (DEL) | VAF 76/200 reads (38%) | catalogued as rs756231131; called by pindel, varscan2
- NAP1L2 | c.82G>A p.G28R | Missense Mutation (SNP) | VAF 40/199 reads (20%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.003); catalogued as COSV65172790; called by muse, mutect2, varscan2
- NAT10 | c.2233T>G p.S745A | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV57665267; called by muse, mutect2, varscan2
- NCAPD2 | c.4018C>T p.P1340S | Missense Mutation (SNP) | VAF 50/121 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.532); catalogued as rs369464603; called by muse, mutect2, varscan2
- NECTIN2 | c.986G>A p.C329Y | Missense Mutation (SNP) | VAF 43/106 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52978705; called by muse, mutect2, varscan2
- NONO | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT tolerated (0.12); PolyPhen benign (0.066); catalogued as rs749334644, COSV52139016; called by muse, mutect2, varscan2
- NOS1 | c.1388C>T p.A463V | Missense Mutation (SNP) | VAF 29/70 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as COSV57616988; called by muse, mutect2, varscan2
- NRDE2 | c.442C>T p.R148C | Missense Mutation (SNP) | VAF 109/231 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as rs187130409; called by muse, mutect2, varscan2
- NRIP1 | c.748del p.R250Gfs*17 | Frame Shift Del (DEL) | VAF 102/274 reads (37%) | catalogued as COSV100012815; called by mutect2, pindel, varscan2
- NSUN5 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 10/129 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV53092804; called by muse, mutect2
- NUCKS1 | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); catalogued as COSV63347874; called by muse, mutect2, varscan2
- NUF2 | c.1102C>A p.Q368K | Missense Mutation (SNP) | VAF 19/177 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.057); catalogued as COSV54845183; called by muse, mutect2, varscan2
- OASL | c.257C>T p.A86V | Missense Mutation (SNP) | VAF 12/132 reads (9%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as rs866108869, COSV57479180; called by muse, mutect2
- OPCML | c.137C>T p.T46M | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.473); catalogued as rs749718972, COSV59402476; called by muse, mutect2, varscan2
- OR10G7 | c.592A>G p.I198V | Missense Mutation (SNP) | VAF 74/304 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.116); catalogued as COSV57867943; called by muse, mutect2
- OR2B2 | c.361G>T p.D121Y | Missense Mutation (SNP) | VAF 133/327 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57579533; called by muse, mutect2, varscan2
- OR4K2 | c.314A>G p.H105R | Missense Mutation (SNP) | VAF 149/383 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53850687, COSV53851948; called by muse, mutect2, varscan2
- OR7A10 | c.205G>A p.V69I | Missense Mutation (SNP) | VAF 164/350 reads (47%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.237); catalogued as rs774022847, COSV50166245; called by muse, mutect2, varscan2
- ORC6 | c.119C>T p.A40V | Missense Mutation (SNP) | VAF 51/105 reads (49%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.784); catalogued as COSV54480031; called by muse, mutect2, varscan2
- OXSM | c.889C>T p.R297W | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs762840852, COSV55001159; called by muse, mutect2, varscan2
- PCDHA6 | c.1841del p.P614Rfs*38 | Frame Shift Del (DEL) | VAF 11/69 reads (16%) | catalogued as rs1554132405; called by mutect2, pindel, varscan2
- PCDHA8 | c.1757G>A p.G586D | Missense Mutation (SNP) | VAF 28/48 reads (58%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.049); catalogued as COSV65329586; called by muse, mutect2, varscan2
- PDK3 | c.1148C>T p.T383M | Missense Mutation (SNP) | VAF 12/111 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as rs1442646183, COSV64793902; called by muse, mutect2, varscan2
- PDPN | c.268G>A p.V90I (on ENST00000621990; = p.V166I on NM_006474.4) | Missense Mutation (SNP) | VAF 95/183 reads (52%) | SIFT tolerated (0.44); PolyPhen benign (0.264); catalogued as rs780201763, COSV53849341; called by muse, mutect2, varscan2
- PDXDC1 | c.2186T>C p.L729S | Missense Mutation (SNP) | VAF 60/143 reads (42%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.162); catalogued as COSV55075096; called by muse, mutect2, varscan2
- PELP1 | c.2090C>T p.S697L | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.022); catalogued as rs558960670, COSV52585752; called by muse, mutect2, varscan2
- PGM3 | c.89C>T p.T30M | Missense Mutation (SNP) | VAF 85/161 reads (53%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.81); catalogued as rs767476579, COSV52285059; called by muse, mutect2, varscan2
- PHACTR1 | c.886C>A p.L296I | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV60674062; called by muse, mutect2, varscan2
- PHACTR4 | c.1589A>G p.E530G (on ENST00000373839 / NM_001350159.2; = p.E540G on NM_023923.4) | Missense Mutation (SNP) | VAF 51/118 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.581); catalogued as COSV65784655; called by muse, mutect2, varscan2
- PHKA2 | c.268C>T p.Q90* | Nonsense Mutation (SNP) | VAF 62/148 reads (42%) | catalogued as COSV66055213; called by muse, mutect2, varscan2
- PIAS3 | c.1774C>A p.R592S | Missense Mutation (SNP) | VAF 59/124 reads (48%) | SIFT tolerated, low confidence (0.39); PolyPhen probably damaging (0.972); catalogued as COSV57907917; called by muse, mutect2, varscan2
- PIK3CB | c.3143C>T p.A1048V | Missense Mutation (SNP) | VAF 103/250 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1170276441, COSV56683565; called by muse, mutect2, varscan2
- PIK3CD | c.2462G>A p.R821H | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs573872848, COSV63128470; called by muse, mutect2, varscan2
- PINK1 | c.1219C>T p.R407W | Missense Mutation (SNP) | VAF 11/19 reads (58%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as rs145876364; called by muse, mutect2, varscan2
- PKHD1 | c.5698C>T p.P1900S | Missense Mutation (SNP) | VAF 37/158 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61863301; called by muse, mutect2, varscan2
- PLEKHH2 | c.2407C>T p.P803S | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT tolerated (0.09); PolyPhen benign (0.265); catalogued as COSV56757523; called by muse, mutect2, varscan2
- PLXNA2 | c.1637C>T p.A546V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); catalogued as rs1022090935, COSV65442785; called by muse, mutect2, varscan2
- PNPLA5 | c.1128G>A p.M376I | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.012); catalogued as COSV53375569; called by muse, mutect2
- POLG2 | c.942G>A p.M314I | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as COSV73347038; called by muse, mutect2, varscan2
- POMT1 | c.1261del p.L421* | Frame Shift Del (DEL) | VAF 66/153 reads (43%) | catalogued as rs749018170; called by mutect2, pindel, varscan2
- POP7 | c.68G>T p.R23M | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs761545949, COSV57450262; called by muse, mutect2, varscan2
- PPARGC1A | c.844C>T p.R282C | Missense Mutation (SNP) | VAF 143/304 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as rs781635737, COSV53523784; called by muse, mutect2, varscan2
- PPFIA4 | c.3327C>T p.D1109= (on ENST00000447715; = p.D1110= on NM_001304331.2 and 1 other RefSeq transcript) | Splice Region (SNP) | VAF 16/34 reads (47%) | catalogued as rs758219065, COSV55315157, COSV55318570; called by muse, mutect2, varscan2
- PPP1R16B | c.1615G>A p.V539I | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT tolerated (0.44); PolyPhen benign (0.085); catalogued as rs142224617; called by muse, mutect2, varscan2
- PPRC1 | c.4084C>T p.Q1362* | Nonsense Mutation (SNP) | VAF 17/134 reads (13%) | catalogued as COSV53387123; called by muse, mutect2, varscan2
- PRM2 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs750334799, COSV54113532; called by muse, mutect2, varscan2
- PRMT5 | c.1096G>A p.A366T | Missense Mutation (SNP) | VAF 27/240 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53547363; called by muse, mutect2, varscan2
- PRRC2C | c.3511A>G p.T1171A (on ENST00000367742; = p.T1169A on NM_015172.4) | Missense Mutation (SNP) | VAF 45/116 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.001); catalogued as COSV58908759; called by muse, mutect2, varscan2
- PSMD6 | c.751C>T p.H251Y | Missense Mutation (SNP) | VAF 23/233 reads (10%) | SIFT tolerated (0.47); PolyPhen benign (0.081); catalogued as COSV55760528; called by muse, mutect2, varscan2
- PTER | c.688C>T p.H230Y | Missense Mutation (SNP) | VAF 112/269 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54346497; called by muse, mutect2, varscan2
- PTPN13 | c.3955G>T p.G1319* (on ENST00000411767 / NM_080683.3; = p.G1300* on NM_006264.3) | Nonsense Mutation (SNP) | VAF 160/411 reads (39%) | catalogued as COSV57412244; called by muse, mutect2, varscan2
- PTPN21 | c.2905G>A p.A969T | Missense Mutation (SNP) | VAF 26/60 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV60850147; called by muse, mutect2, varscan2
- PTPRN2 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs755323823, COSV67032040; called by muse, mutect2, varscan2
- RABGEF1 | c.1028G>A p.R343H (on ENST00000439720 / NM_001287061.2; = p.R330H on NM_014504.3 and 29 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 72/181 reads (40%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.969); catalogued as COSV53163649; called by muse, mutect2, varscan2
- RADX | c.742C>T p.R248* | Nonsense Mutation (SNP) | VAF 98/201 reads (49%) | catalogued as rs975208319, COSV65319438; called by muse, mutect2, varscan2
- RAPGEF4 | c.413T>C p.I138T | Missense Mutation (SNP) | VAF 94/186 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV51403733; called by muse, mutect2, varscan2
- RAPGEF4 | c.916_918del p.K306del | In Frame Del (DEL) | VAF 12/26 reads (46%) | catalogued as rs1186346013; called by pindel, varscan2
- RASAL3 | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT tolerated (0.28); PolyPhen benign (0.027); catalogued as rs750343840, COSV59140672; called by muse, mutect2, varscan2
- RBL1 | c.121G>A p.D41N | Missense Mutation (SNP) | VAF 5/14 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.005); catalogued as rs775983957, COSV60331443; called by muse, mutect2, varscan2
- RBP7 | c.232C>A p.L78M | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.123); catalogued as COSV53813517; called by muse, mutect2
- RMDN3 | c.1098C>G p.H366Q | Missense Mutation (SNP) | VAF 126/329 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); catalogued as COSV53024907; called by muse, mutect2, varscan2
- RNF43 | c.1976del p.G659Vfs*41 | Frame Shift Del (DEL) | VAF 12/136 reads (9%) | catalogued as rs755128667, COSV68457540; called by mutect2, pindel
- RP1 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 14/29 reads (48%) | SIFT tolerated (0.23); PolyPhen benign (0.019); catalogued as rs755833719, COSV55109953, COSV55120295; called by muse, mutect2, varscan2
- RPUSD3 | c.392T>C p.V131A | Missense Mutation (SNP) | VAF 104/256 reads (41%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as COSV67579311; called by muse, mutect2, varscan2
- RTKN | c.1549C>T p.R517* (on ENST00000272430 / NM_001015055.2; = p.R504* on NM_033046.2) | Nonsense Mutation (SNP) | VAF 28/70 reads (40%) | catalogued as rs78574572, COSV51965006; called by muse, mutect2, varscan2
- RTKN2 | c.1348del p.I450Lfs*67 | Frame Shift Del (DEL) | VAF 72/171 reads (42%) | catalogued as rs759252078; called by mutect2, varscan2
- RYR1 | c.7303C>T p.R2435C | Missense Mutation (SNP) | VAF 21/33 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV62096581; called by muse, mutect2, varscan2
- RYR2 | c.13326C>T p.A4442= | Splice Region (SNP) | VAF 10/92 reads (11%) | catalogued as rs768161152, COSV63699041; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- RYR3 | c.6998G>A p.S2333N (on ENST00000389232; = p.S2334N on NM_001036.6) | Missense Mutation (SNP) | VAF 12/17 reads (71%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs199928344, COSV63109738; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC16A | c.1689dup p.K564* | Frame Shift Ins (INS) | VAF 11/18 reads (61%) | catalogued as rs1187752611; called by mutect2, varscan2
- SEC31A | c.1384del p.I462Lfs*16 | Frame Shift Del (DEL) | VAF 32/76 reads (42%) | catalogued as rs748463349, COSV52348607; called by mutect2, varscan2
- SEMA3C | c.74C>A p.P25H | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV54851591; called by muse, mutect2, varscan2
- SEMG2 | c.364C>T p.H122Y | Missense Mutation (SNP) | VAF 141/299 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV65647719; called by muse, mutect2, varscan2
- SERPINB9 | c.170C>T p.A57V | Missense Mutation (SNP) | VAF 114/271 reads (42%) | SIFT tolerated (0.87); PolyPhen benign (0.005); catalogued as COSV66233922; called by muse, mutect2, varscan2
- SERPINF1 | c.718A>T p.R240W | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV54616745; called by muse, mutect2, varscan2
- SH3GL2 | c.536C>T p.P179L | Missense Mutation (SNP) | VAF 73/173 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.388); catalogued as rs1436198291, COSV66047873; called by muse, mutect2, varscan2
- SHROOM3 | c.2449A>G p.T817A | Missense Mutation (SNP) | VAF 31/71 reads (44%) | SIFT tolerated (0.65); PolyPhen benign (0.003); catalogued as COSV56034628; called by muse, mutect2, varscan2
- SIGLEC5 | c.37+1del p.X13_splice | Splice Site (DEL) | VAF 18/114 reads (16%) | catalogued as rs769090558; called by mutect2, pindel
- SIX2 | c.253C>T p.Q85* | Nonsense Mutation (SNP) | VAF 4/22 reads (18%) | catalogued as rs11540435, COSV57391420; called by muse, mutect2
- SLC12A4 | c.3032C>T p.P1011L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.981); catalogued as rs1567412008, COSV50453817; called by muse, mutect2, varscan2
- SLC16A12 | c.219del p.F73Lfs*22 | Frame Shift Del (DEL) | VAF 33/88 reads (38%) | catalogued as rs760181506; called by mutect2, varscan2
- SLC30A3 | c.647C>A p.P216Q | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT tolerated (0.54); PolyPhen benign (0.154); catalogued as COSV51985661, COSV51986814; called by muse, mutect2, varscan2
- SLC35G3 | c.850G>A p.A284T | Missense Mutation (SNP) | VAF 51/166 reads (31%) | SIFT tolerated (0.55); PolyPhen benign (0.011); catalogued as rs748027779, COSV52012021; called by muse, mutect2, varscan2
- SLC4A5 | c.2483C>T p.P828L | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760956666, COSV61030424; called by mutect2, varscan2
- SLC5A11 | c.1207G>A p.D403N | Missense Mutation (SNP) | VAF 4/90 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61740260; called by muse, mutect2
- SLC5A3 | c.500G>A p.G167D | Missense Mutation (SNP) | VAF 63/207 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV62971648; called by muse, mutect2, varscan2
- SLC8A1 | c.2593G>A p.A865T | Missense Mutation (SNP) | VAF 24/121 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs772823388, COSV60489067; called by muse, mutect2, varscan2
- SLC9A8 | c.1223G>A p.R408Q | Missense Mutation (SNP) | VAF 158/341 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs760572395, COSV64289743; called by muse, mutect2, varscan2
- SLCO1B3 | c.977del p.F326Sfs*4 | Frame Shift Del (DEL) | VAF 56/146 reads (38%) | catalogued as rs769005039, COSV53944787; ClinVar: uncertain significance; called by mutect2, pindel, varscan2
- SLFNL1 | c.802G>A p.V268M | Missense Mutation (SNP) | VAF 33/68 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752272148, COSV57235081; called by muse, mutect2, varscan2
- SMAP1 | c.613del p.S205Vfs*15 (on ENST00000370455 / NM_001044305.3; = p.S178Vfs*15 on NM_021940.5) | Frame Shift Del (DEL) | VAF 6/35 reads (17%) | catalogued as rs766085867, COSV100391091; called by mutect2, pindel
- SMG7 | c.2545del p.M849* | Frame Shift Del (DEL) | VAF 46/214 reads (21%) | catalogued as rs749889899; called by mutect2, varscan2
- SPAG1 | c.26T>C p.L9S | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as COSV52561380; called by muse, mutect2, varscan2
- SPON1 | c.2330G>A p.R777H | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs868925163, COSV59964340; called by muse, mutect2, varscan2
- SPPL2C | c.1856del p.P619Lfs*7 | Frame Shift Del (DEL) | VAF 28/90 reads (31%) | catalogued as COSV100233975; called by mutect2, pindel, varscan2
- SRPRA | c.929C>T p.P310L | Missense Mutation (SNP) | VAF 37/210 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.065); catalogued as COSV55007836; called by muse, mutect2, varscan2
- SS18L1 | c.1167C>T p.G389= | Splice Region (SNP) | VAF 3/40 reads (8%) | catalogued as COSV59211998; called by muse, mutect2
- STAMBPL1 | c.1214del p.K405Rfs*21 | Frame Shift Del (DEL) | VAF 8/70 reads (11%) | catalogued as rs752994755; called by mutect2, varscan2
- STARD13 | c.2747G>A p.G916D (on ENST00000336934 / NM_001243476.3; = p.G798D on NM_052851.3) | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.68); PolyPhen benign (0.021); catalogued as COSV55233785, COSV99063389; called by muse, mutect2
- STEAP2 | c.680del p.F227Sfs*9 | Frame Shift Del (DEL) | VAF 56/175 reads (32%) | catalogued as rs754344704; called by mutect2, varscan2
- STK31 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1282523650, COSV63454154; called by muse, mutect2, varscan2
- SULT6B1 | c.257del p.K86Sfs*21 (on ENST00000535679 / NM_001367551.1; = p.K48Sfs*21 on NM_001032377.2) | Frame Shift Del (DEL) | VAF 43/100 reads (43%) | catalogued as rs747003550; called by mutect2, varscan2
- SV2A | c.156G>T p.E52D | Missense Mutation (SNP) | VAF 132/310 reads (43%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.015); catalogued as rs782780934, COSV64965400; called by muse, mutect2, varscan2
- SVEP1 | c.6575G>T p.W2192L | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52836678, COSV52841598; called by muse, mutect2
- SYT6 | c.1441G>A p.E481K (on ENST00000610222 / NM_001366225.1; = p.E396K on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.582); catalogued as rs370048571, COSV65774695; called by muse, mutect2, varscan2
- TAB2 | c.562G>T p.G188C | Missense Mutation (SNP) | VAF 153/400 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV53853879; called by muse, mutect2, varscan2
- TANC2 | c.2290C>T p.H764Y | Missense Mutation (SNP) | VAF 56/117 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1490007629, COSV67337795; called by muse, mutect2, varscan2
- TARBP2 | c.686C>A p.P229H (on ENST00000266987 / NM_134323.2; = p.P208H on NM_004178.4) | Missense Mutation (SNP) | VAF 12/145 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV57200182; called by muse, mutect2
- TBC1D4 | c.3149C>T p.S1050L | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.995); catalogued as rs767493446, COSV66490398; called by muse, mutect2, varscan2
- TBCEL | c.1149G>A p.M383I | Missense Mutation (SNP) | VAF 87/190 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.001); catalogued as COSV52461077; called by muse, mutect2, varscan2
- TBKBP1 | c.103G>A p.D35N | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); catalogued as COSV64653530; called by muse, mutect2, varscan2
- TCF20 | c.841G>A p.A281T | Missense Mutation (SNP) | VAF 196/453 reads (43%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV59494165, COSV59495270; called by muse, mutect2, varscan2
- TENM4 | c.4675C>T p.R1559* | Nonsense Mutation (SNP) | VAF 23/93 reads (25%) | catalogued as rs749216369, COSV53606167; called by muse, mutect2, varscan2
- TENT2 | c.167T>C p.L56P | Missense Mutation (SNP) | VAF 28/74 reads (38%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.564); catalogued as COSV57138329; called by muse, mutect2, varscan2
- TFPI | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 42/163 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.892); catalogued as rs757564692, COSV51903456; called by muse, mutect2, varscan2
- TGS1 | c.1048G>A p.E350K | Missense Mutation (SNP) | VAF 66/150 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as COSV52701785; called by muse, mutect2, varscan2
- TLN1 | c.7205C>T p.A2402V | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as rs200286479, COSV59209694; called by muse, mutect2, varscan2
- TNFRSF10D | c.179G>A p.R60Q | Missense Mutation (SNP) | VAF 43/73 reads (59%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as rs200139123, COSV57036847; called by muse, mutect2, varscan2
- TNKS2 | c.2988G>T p.K996N | Missense Mutation (SNP) | VAF 20/56 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as COSV65416163; called by muse, mutect2, varscan2
- TNRC6B | c.2128G>A p.G710R | Missense Mutation (SNP) | VAF 25/77 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs765016548, COSV57301758; called by muse, mutect2, varscan2
- TOP2B | c.3922_3924del p.K1308del (on ENST00000264331 / NM_001330700.2; = p.K1303del on NM_001068.3) | In Frame Del (DEL) | VAF 6/22 reads (27%) | catalogued as rs781031811; called by pindel, varscan2
- TRIM2 | c.1631G>A p.S544N (on ENST00000437508; = p.S571N on NM_015271.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV58636534; called by muse, mutect2, varscan2
- TRIP13 | c.803C>A p.T268N | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.01); catalogued as COSV51320870, COSV99386553; called by muse, mutect2, varscan2
- TRPC1 | c.830G>A p.R277Q (on ENST00000476941 / NM_001251845.2; = p.R243Q on NM_003304.4) | Missense Mutation (SNP) | VAF 44/112 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs1347931843, COSV56427520; called by muse, mutect2, varscan2
- TSPYL5 | c.409dup p.R137Pfs*18 | Frame Shift Ins (INS) | VAF 30/80 reads (38%) | catalogued as rs775143186; called by mutect2, pindel, varscan2
- TSSK1B | c.478C>T p.R160C | Missense Mutation (SNP) | VAF 65/149 reads (44%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.964); catalogued as rs576153450, COSV66815669; called by muse, mutect2, varscan2
- TTK | c.484del p.S162Vfs*9 | Frame Shift Del (DEL) | VAF 26/105 reads (25%) | catalogued as rs751135082; called by mutect2, pindel, varscan2
- TTLL9 | c.289C>T p.R97W | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs760256556, COSV60594570; called by muse, mutect2, varscan2
- TTN | c.64715G>A p.R21572H (on ENST00000591111; = p.R14148H on NM_003319.4) | Missense Mutation (SNP) | VAF 59/186 reads (32%) | PolyPhen probably damaging (0.998); catalogued as rs374883884, COSV60198099; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UBE3A | c.1589A>G p.D530G | Missense Mutation (SNP) | VAF 18/231 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV51668427; called by muse, mutect2
- UGT2B15 | c.1261A>G p.M421V | Missense Mutation (SNP) | VAF 18/580 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.626); catalogued as COSV57735641; called by muse, mutect2
- UPF2 | c.3099A>T p.E1033D | Missense Mutation (SNP) | VAF 30/101 reads (30%) | SIFT tolerated (0.62); PolyPhen benign (0.003); catalogued as rs1367060563, COSV62658267; called by muse, mutect2, varscan2
- USH2A | c.13726G>T p.E4576* | Nonsense Mutation (SNP) | VAF 199/470 reads (42%) | catalogued as COSV56401434; called by muse, mutect2, varscan2
- USP35 | c.2219C>T p.T740I | Missense Mutation (SNP) | VAF 90/187 reads (48%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.813); catalogued as rs1169381180, COSV71573094; called by muse, mutect2, varscan2
- USP48 | c.1688G>A p.R563H | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.854); catalogued as rs770084847, COSV57612300; called by muse, mutect2, varscan2
- VWA8 | c.2262C>A p.F754L | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV55696575, COSV55700782; called by muse, mutect2, varscan2
- WDR53 | c.53C>T p.A18V | Missense Mutation (SNP) | VAF 36/79 reads (46%) | SIFT tolerated (0.89); PolyPhen benign (0.007); catalogued as COSV60284574; called by muse, mutect2, varscan2
- WRAP53 | c.1565del p.A522Gfs*26 | Frame Shift Del (DEL) | VAF 22/54 reads (41%) | catalogued as rs373064567, COSV56832921, COSV56833408; called by mutect2, pindel, varscan2
- XKR7 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 15/35 reads (43%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as rs201142404, COSV101629269, COSV73812912; called by muse, mutect2, varscan2
- XPOT | c.378del p.F126Lfs*6 | Frame Shift Del (DEL) | VAF 48/105 reads (46%) | catalogued as rs762052135; called by mutect2, varscan2
- XYLT1 | c.896G>A p.R299Q | Missense Mutation (SNP) | VAF 13/115 reads (11%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.996); catalogued as rs200980375, COSV54490730; called by muse, mutect2, varscan2
- YTHDC2 | c.1354C>T p.Q452* | Nonsense Mutation (SNP) | VAF 160/334 reads (48%) | catalogued as COSV50747117; called by muse, varscan2
- ZBTB1 | c.1147del p.S383Vfs*6 | Frame Shift Del (DEL) | VAF 17/98 reads (17%) | catalogued as rs747075448, COSV62437585; called by mutect2, varscan2
- ZBTB9 | c.575C>G p.T192S | Missense Mutation (SNP) | VAF 54/109 reads (50%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV67702252; called by muse, mutect2, varscan2
- ZC3H18 | c.1147G>A p.G383R | Missense Mutation (SNP) | VAF 57/167 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs767569235, COSV56326376; called by muse, mutect2, varscan2
- ZDHHC23 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.1); PolyPhen benign (0.048); catalogued as rs370624022; called by mutect2, varscan2
- ZFHX3 | c.2792G>A p.G931D | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.791); catalogued as COSV51726891; called by muse, mutect2, varscan2
- ZFYVE16 | c.1024G>A p.A342T | Missense Mutation (SNP) | VAF 24/131 reads (18%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV62016504; called by muse, mutect2, varscan2
- ZMYM3 | c.1849C>T p.R617C | Missense Mutation (SNP) | VAF 31/54 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV58739373; called by muse, mutect2, varscan2
- ZNF267 | c.1531C>T p.R511W | Missense Mutation (SNP) | VAF 73/168 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.383); catalogued as rs774745782, COSV56251685; called by muse, mutect2, varscan2
- ZNF341 | c.1060G>A p.A354T (on ENST00000375200 / NM_001282935.1; = p.A347T on NM_032819.4) | Missense Mutation (SNP) | VAF 51/202 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.138); catalogued as COSV61010110; called by muse, mutect2, varscan2
- ZNF862 | c.249dup p.Q84Tfs*71 | Frame Shift Ins (INS) | VAF 20/42 reads (48%) | catalogued as rs755241977; called by mutect2, varscan2
- ZNF91 | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 70/494 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1235412364, COSV56088506; called by muse, mutect2, varscan2
- ZNRF3 | c.1129G>A p.A377T (on ENST00000544604 / NM_001206998.2; = p.A277T on NM_032173.3) | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT tolerated (0.46); PolyPhen benign (0.415); catalogued as rs768773900, COSV60436453; called by muse, mutect2, varscan2
- ZSCAN4 | c.191G>T p.R64I | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.26); catalogued as COSV59000838; called by muse, mutect2, varscan2
- AREG | c.556A>G p.M186V | Missense Mutation (SNP) | VAF 12/270 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2
- BTNL8 | c.747dup p.G250Wfs*56 (on ENST00000340184 / NM_001040462.3; = p.G250Wfs*15 on NM_024850.2) | Frame Shift Ins (INS) | VAF 86/610 reads (14%) | called by mutect2, varscan2
- CASK | c.124del p.I42Lfs*4 | Frame Shift Del (DEL) | VAF 95/252 reads (38%) | called by mutect2, pindel, varscan2
- COL12A1 | c.3135del p.T1046Qfs*7 | Frame Shift Del (DEL) | VAF 79/183 reads (43%) | called by mutect2, pindel, varscan2
- COL15A1 | c.3117del p.G1040Efs*113 | Frame Shift Del (DEL) | VAF 58/150 reads (39%) | called by mutect2, pindel, varscan2
- COL23A1 | c.1065dup p.K356Qfs*31 | Frame Shift Ins (INS) | VAF 61/162 reads (38%) | called by mutect2, pindel, varscan2
- CSGALNACT1 | c.1594del p.T532Hfs*43 | Frame Shift Del (DEL) | VAF 30/188 reads (16%) | called by mutect2, varscan2
- CTCF | c.409del p.A137Lfs*17 | Frame Shift Del (DEL) | VAF 77/216 reads (36%) | called by mutect2, pindel, varscan2
- DCDC1 | c.5223del p.E1742Sfs*2 (on ENST00000597505 / NM_001367979.1; = p.E849Sfs*2 on NM_020869.3) | Frame Shift Del (DEL) | VAF 31/91 reads (34%) | called by mutect2, pindel, varscan2
- DNAH3 | c.7123del p.I2375Sfs*8 | Frame Shift Del (DEL) | VAF 57/237 reads (24%) | called by mutect2, pindel, varscan2
- E2F5 | c.329del p.N110Tfs*8 | Frame Shift Del (DEL) | VAF 17/45 reads (38%) | called by mutect2, pindel, varscan2
- FREM1 | c.1398del p.L470Sfs*56 | Frame Shift Del (DEL) | VAF 59/144 reads (41%) | called by mutect2, varscan2
- FRMPD1 | c.2371dup p.S791Ffs*13 | Frame Shift Ins (INS) | VAF 86/246 reads (35%) | called by mutect2, pindel, varscan2
- GPRC5B | c.793del p.D265Mfs*143 | Frame Shift Del (DEL) | VAF 19/51 reads (37%) | called by mutect2, pindel, varscan2
- JAK1 | c.2580del p.K860Nfs*16 | Frame Shift Del (DEL) | VAF 26/155 reads (17%) | called by mutect2, varscan2
- LRRK2 | c.6782dup p.N2261Kfs*9 | Frame Shift Ins (INS) | VAF 24/54 reads (44%) | called by mutect2, varscan2
- MAGEA10 | c.944del p.L315Wfs*4 | Frame Shift Del (DEL) | VAF 95/244 reads (39%) | called by mutect2, pindel, varscan2
- MAN1C1 | c.1326del p.I443Ffs*16 | Frame Shift Del (DEL) | VAF 9/47 reads (19%) | called by mutect2, pindel, varscan2
- MARS2 | c.705del p.E236Nfs*6 | Frame Shift Del (DEL) | VAF 15/40 reads (38%) | called by mutect2, pindel, varscan2
- MCM6 | c.2311del p.R771Efs*3 | Frame Shift Del (DEL) | VAF 120/340 reads (35%) | called by mutect2, pindel, varscan2
- MICAL1 | c.360_361del p.R121Pfs*20 | Frame Shift Del (DEL) | VAF 6/22 reads (27%) | called by pindel, varscan2
- MRPL2 | c.873del p.M292* | Frame Shift Del (DEL) | VAF 44/127 reads (35%) | called by pindel, varscan2
- MSL3 | c.873dup p.L292Sfs*4 (on ENST00000312196 / NM_078629.4; = p.L126Sfs*4 on NM_006800.4) | Frame Shift Ins (INS) | VAF 86/236 reads (36%) | called by mutect2, pindel, varscan2
- MTF1 | c.1385dup p.A463Cfs*19 | Frame Shift Ins (INS) | VAF 28/73 reads (38%) | called by mutect2, pindel, varscan2
- MYO9A | c.4264del p.Y1422Ifs*8 | Frame Shift Del (DEL) | VAF 24/174 reads (14%) | called by mutect2, varscan2
- NBPF7 | n.317G>T | Splice Region (SNP) | VAF 123/256 reads (48%) | called by muse, mutect2, varscan2
- NIPBL | c.4226_4227del p.T1409Nfs*20 | Frame Shift Del (DEL) | VAF 17/44 reads (39%) | called by pindel, varscan2
- NOSTRIN | c.414_416del p.K139del (on ENST00000317647 / NM_001039724.4; = p.K61del on NM_052946.3) | In Frame Del (DEL) | VAF 32/136 reads (24%) | called by pindel, varscan2
- OR13C8 | c.926del p.N309Tfs*? | Frame Shift Del (DEL) | VAF 56/161 reads (35%) | called by mutect2, pindel, varscan2
- OR2A12 | c.530del p.F177Sfs*30 | Frame Shift Del (DEL) | VAF 159/417 reads (38%) | called by mutect2, pindel, varscan2
- PIGW | c.976_977del p.M326Afs*2 | Frame Shift Del (DEL) | VAF 41/121 reads (34%) | called by pindel, varscan2
- POSTN | c.542del p.N181Mfs*3 | Frame Shift Del (DEL) | VAF 18/99 reads (18%) | called by mutect2, pindel, varscan2
- POU5F1 | c.1040del p.P347Lfs*50 | Frame Shift Del (DEL) | VAF 4/30 reads (13%) | called by pindel, varscan2
- PPARGC1B | c.408del p.S137Afs*69 | Frame Shift Del (DEL) | VAF 12/52 reads (23%) | called by mutect2, pindel, varscan2
- PPP1R2 | c.410dup p.R138Afs*4 | Frame Shift Ins (INS) | VAF 82/199 reads (41%) | called by mutect2, varscan2
- PPP3CB | c.101del p.P34Qfs*5 | Frame Shift Del (DEL) | VAF 56/226 reads (25%) | called by mutect2, pindel, varscan2
- PRKCA | c.1541del p.P514Rfs*59 | Frame Shift Del (DEL) | VAF 27/129 reads (21%) | called by mutect2, pindel, varscan2
- PTPDC1 | c.1831del p.R611Gfs*3 (on ENST00000375360 / NM_177995.3; = p.R663Gfs*3 on NM_152422.4) | Frame Shift Del (DEL) | VAF 84/236 reads (36%) | called by mutect2, pindel, varscan2
- PTPN20 | c.799C>A p.H267N | Missense Mutation (SNP) | VAF 202/804 reads (25%) | SIFT tolerated (0.13); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- SEPTIN9 | c.1423del p.Q475Rfs*13 (on ENST00000427177 / NM_001113491.2; = p.Q457Rfs*13 on NM_006640.4) | Frame Shift Del (DEL) | VAF 44/124 reads (35%) | called by mutect2, pindel, varscan2
- SIX4 | c.2292dup p.E765Rfs*12 | Frame Shift Ins (INS) | VAF 44/115 reads (38%) | called by mutect2, pindel, varscan2
- SNX21 | c.302del p.P101Hfs*35 | Frame Shift Del (DEL) | VAF 28/89 reads (31%) | called by mutect2, pindel, varscan2
- SPATA31D1 | c.1647del p.Q551Nfs*28 | Frame Shift Del (DEL) | VAF 115/460 reads (25%) | called by mutect2, pindel, varscan2
- SRPX | c.677del p.P226Qfs*32 | Frame Shift Del (DEL) | VAF 54/137 reads (39%) | called by mutect2, varscan2
- TESMIN | c.1205dup p.N402Kfs*3 | Frame Shift Ins (INS) | VAF 26/65 reads (40%) | called by mutect2, pindel, varscan2
- TEX13A | c.469del p.A157Qfs*196 | Frame Shift Del (DEL) | VAF 16/38 reads (42%) | called by mutect2, varscan2
- TGIF1 | c.625_626del p.Q209Efs*57 (on ENST00000330513 / NM_001374396.1; = p.Q229Efs*57 on NM_003244.4) | Frame Shift Del (DEL) | VAF 26/192 reads (14%) | called by pindel, varscan2
- TIMM21 | c.300del p.V101* | Frame Shift Del (DEL) | VAF 38/92 reads (41%) | called by mutect2, pindel, varscan2
- TMEM176B | c.718del p.L240* | Frame Shift Del (DEL) | VAF 128/310 reads (41%) | called by mutect2, pindel, varscan2
- TRAV26-1 | c.104C>T p.A35V | Missense Mutation (SNP) | VAF 165/393 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ZBTB41 | c.1870del p.I624Yfs*88 | Frame Shift Del (DEL) | VAF 24/156 reads (15%) | called by mutect2, pindel, varscan2
- ZC3HC1 | c.848del p.G283Afs*9 | Frame Shift Del (DEL) | VAF 28/73 reads (38%) | called by mutect2, pindel, varscan2
- ZNF292 | c.3938dup p.N1314* | Frame Shift Ins (INS) | VAF 23/79 reads (29%) | called by mutect2, pindel, varscan2
- AADAC | c.1194T>C p.N398= | Silent (SNP) | VAF 48/112 reads (43%) | catalogued as COSV51760386; called by muse, mutect2, varscan2
- ABCB10 | c.1605A>C p.T535= | Silent (SNP) | VAF 31/243 reads (13%) | catalogued as COSV60622482; called by muse, mutect2, varscan2
- ABT1 | c.384G>A p.T128= | Silent (SNP) | VAF 33/74 reads (45%) | catalogued as rs782736817, COSV51292071; called by muse, mutect2, varscan2
- AC098582.1 | c.657C>T p.A219= | Silent (SNP) | VAF 25/68 reads (37%) | catalogued as rs373505048; called by muse, mutect2, varscan2
- ACE | c.2250C>A p.T750= | Silent (SNP) | VAF 16/34 reads (47%) | catalogued as COSV52010354; called by muse, mutect2, varscan2
- ACTA2 | c.1092C>T p.Y364= | Silent (SNP) | VAF 73/219 reads (33%) | catalogued as rs754695149, COSV56517305; called by muse, mutect2, varscan2
- AKAP17A | c.1791C>T p.D597= | Silent (SNP) | VAF 4/18 reads (22%) | called by muse, mutect2
- ANK3 | c.5031A>G p.S1677= | Silent (SNP) | VAF 68/226 reads (30%) | catalogued as COSV55069824; called by muse, mutect2, varscan2
- APC | c.2718T>C p.S906= | Silent (SNP) | VAF 94/197 reads (48%) | catalogued as COSV57362938; called by muse, mutect2, varscan2
- APEX2 | c.336C>T p.C112= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs1463337406, COSV66624272; called by muse, mutect2, varscan2
- APOB | c.3318C>A p.L1106= | Silent (SNP) | VAF 47/133 reads (35%) | catalogued as rs1558567515, COSV51944208; called by muse, mutect2, varscan2
- ASL | c.1026G>A p.V342= | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV59188867; called by muse, mutect2
- ATXN1 | c.2139C>T p.A713= | Silent (SNP) | VAF 37/92 reads (40%) | catalogued as rs767446655, COSV55223105; called by muse, mutect2, varscan2
- BAHD1 | c.1401C>A p.G467= | Silent (SNP) | VAF 16/26 reads (62%) | catalogued as COSV69083787, COSV69084293; called by muse, mutect2, varscan2
- BCAS1 | c.630C>T p.D210= | Silent (SNP) | VAF 204/448 reads (46%) | catalogued as rs1043918388, COSV65085333; called by muse, mutect2, varscan2
- BEND3 | c.1656C>T p.D552= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as COSV64681677; called by muse, mutect2, varscan2
- BIRC6 | c.1413A>G p.G471= | Silent (SNP) | VAF 10/180 reads (6%) | catalogued as COSV70202918; called by muse, mutect2
- CASK | c.2670C>T p.F890= (on ENST00000378163 / NM_001367721.1; = p.F885= on NM_003688.3) | Silent (SNP) | VAF 69/167 reads (41%) | catalogued as rs773214246, COSV59364492; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHD3 | c.252C>T p.Y84= | Silent (SNP) | VAF 5/86 reads (6%) | catalogued as rs1257053893, COSV57877798; called by muse, mutect2
- CPNE2 | c.400C>T p.L134= | Silent (SNP) | VAF 22/38 reads (58%) | catalogued as COSV51963722; called by muse, mutect2, varscan2
- DCDC2 | c.1248G>A p.L416= | Silent (SNP) | VAF 181/394 reads (46%) | catalogued as COSV65829370; called by muse, mutect2, varscan2
- DDX42 | c.1749G>A p.T583= | Silent (SNP) | VAF 66/147 reads (45%) | catalogued as rs774488957, COSV63790708; called by muse, mutect2, varscan2
- DEFB110 | c.180C>T p.C60= | Silent (SNP) | VAF 9/119 reads (8%) | catalogued as rs779849256, COSV101182554, COSV67018056; called by muse, mutect2
- DENND4C | c.3696T>C p.S1232= (on ENST00000434457 / NM_001330640.2; = p.S1183= on NM_017925.7) | Silent (SNP) | VAF 64/155 reads (41%) | catalogued as rs1225723304, COSV63009297; called by muse, mutect2, varscan2
- DNAH11 | c.990C>T p.L330= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as rs376448045; ClinVar: likely benign; called by muse, mutect2, varscan2
- DNAH5 | c.12015T>C p.P4005= | Silent (SNP) | VAF 54/127 reads (43%) | catalogued as COSV54239565; called by muse, mutect2, varscan2
- DPP3 | c.1515C>T p.S505= | Silent (SNP) | VAF 9/20 reads (45%) | catalogued as COSV64757366; called by muse, mutect2, varscan2
- DPYSL5 | c.1332C>T p.R444= | Silent (SNP) | VAF 4/58 reads (7%) | catalogued as COSV56514290; called by muse, mutect2
- DRGX | c.723G>A p.A241= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as rs777835103, COSV65136309; called by muse, mutect2, varscan2
- DUSP10 | c.1284G>A p.R428= | Silent (SNP) | VAF 61/175 reads (35%) | catalogued as rs778427497, COSV60458872; called by muse, mutect2, varscan2
- DVL3 | c.2052C>T p.G684= | Silent (SNP) | VAF 9/19 reads (47%) | catalogued as COSV53049151; called by muse, mutect2, varscan2
- ENGASE | c.588T>C p.N196= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as rs199931098; called by muse, mutect2, varscan2
- EP400 | c.5712C>A p.T1904= | Silent (SNP) | VAF 30/90 reads (33%) | catalogued as COSV57779135; called by muse, mutect2, varscan2
- FAAP100 | c.1377G>A p.L459= | Silent (SNP) | VAF 5/14 reads (36%) | catalogued as COSV59884340, COSV59886631; called by muse, mutect2, varscan2
- FAM83G | c.2328C>A p.T776= | Silent (SNP) | VAF 6/27 reads (22%) | catalogued as COSV58760172; called by muse, mutect2, varscan2
- FANCA | c.690C>T p.V230= | Silent (SNP) | VAF 5/75 reads (7%) | catalogued as rs942275917, COSV66882699; called by muse, mutect2
- FBN2 | c.8529C>T p.S2843= | Silent (SNP) | VAF 88/179 reads (49%) | catalogued as rs140437100; called by muse, mutect2, varscan2
- FREM2 | c.741C>T p.G247= | Silent (SNP) | VAF 13/28 reads (46%) | catalogued as rs1489880344, COSV54837628; called by muse, mutect2, varscan2
- FYB2 | c.522C>T p.G174= | Silent (SNP) | VAF 29/343 reads (8%) | catalogued as COSV58587127; called by muse, mutect2
- G3BP1 | c.1389G>A p.A463= | Silent (SNP) | VAF 37/94 reads (39%) | catalogued as rs1561538728, COSV62366530; called by muse, mutect2, varscan2
- GAS7 | c.1413T>C p.P471= (on ENST00000432992 / NM_201433.2; = p.P331= on NM_003644.3) | Silent (SNP) | VAF 33/80 reads (41%) | catalogued as rs759960358, COSV60440235; called by muse, mutect2, varscan2
- GET1 | c.318C>T p.V106= | Silent (SNP) | VAF 30/88 reads (34%) | catalogued as rs147098320; called by muse, mutect2, varscan2
- GSN | c.276C>T p.G92= | Silent (SNP) | VAF 34/63 reads (54%) | catalogued as rs774617795, COSV57997291; ClinVar: likely benign; called by muse, mutect2, varscan2
- HERC1 | c.5530C>T p.L1844= | Silent (SNP) | VAF 32/67 reads (48%) | catalogued as COSV71249020; called by muse, mutect2, varscan2
- HIVEP2 | c.3436C>T p.L1146= | Silent (SNP) | VAF 38/79 reads (48%) | catalogued as COSV50027416; called by muse, mutect2, varscan2
- HMCN1 | c.567T>C p.I189= | Silent (SNP) | VAF 80/180 reads (44%) | catalogued as COSV54919463; called by muse, mutect2, varscan2
- IFNG | c.51T>C p.G17= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as rs1206771822, COSV57491721; called by muse, mutect2, varscan2
- KCNH1 | c.1740G>A p.P580= (on ENST00000271751 / NM_172362.3; = p.P553= on NM_002238.4) | Silent (SNP) | VAF 34/74 reads (46%) | catalogued as rs145789974; called by muse, mutect2, varscan2
- KIF22 | c.345G>A p.L115= | Silent (SNP) | VAF 34/67 reads (51%) | catalogued as COSV50716750; called by muse, mutect2, varscan2
- KIRREL2 | c.1668C>T p.S556= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV52878354; called by muse, mutect2, varscan2
- KLHDC8B | c.973C>T p.L325= | Silent (SNP) | VAF 31/59 reads (53%) | catalogued as COSV60412260; called by muse, mutect2, varscan2
- KMT5B | c.714G>A p.E238= | Silent (SNP) | VAF 30/85 reads (35%) | catalogued as rs911373186, COSV58566080; called by muse, mutect2, varscan2
- KRTAP9-9 | c.504C>T p.C168= | Silent (SNP) | VAF 137/512 reads (27%) | catalogued as rs758315892, COSV67454120; called by muse, mutect2, varscan2
- KSR2 | c.2661C>T p.G887= | Silent (SNP) | VAF 46/99 reads (46%) | catalogued as COSV56678111; called by muse, mutect2, varscan2
- LRRC20 | c.66C>T p.S22= | Silent (SNP) | VAF 51/114 reads (45%) | catalogued as rs748634064, COSV62938376; called by muse, mutect2, varscan2
- MDM1 | c.1059G>A p.T353= | Silent (SNP) | VAF 38/85 reads (45%) | catalogued as rs752400457, COSV57444473; called by muse, mutect2, varscan2
- MEGF11 | c.1245C>T p.C415= | Silent (SNP) | VAF 9/28 reads (32%) | catalogued as COSV56555414; called by muse, mutect2, varscan2
- MEOX2 | c.753A>G p.G251= | Silent (SNP) | VAF 7/163 reads (4%) | catalogued as COSV56292528; called by muse, mutect2
- MFAP3L | c.393C>T p.Y131= | Silent (SNP) | VAF 16/149 reads (11%) | catalogued as rs751263509, COSV64372557; called by muse, mutect2, varscan2
- MGAM | c.4314C>T p.D1438= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as rs756672690, COSV72074571; called by muse, mutect2, varscan2
- MIOS | c.264A>G p.V88= | Silent (SNP) | VAF 56/217 reads (26%) | catalogued as COSV60769724; called by muse, mutect2, varscan2
- MROH2B | c.3771C>T p.H1257= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs770621522, COSV68185864; called by muse, mutect2, varscan2
- MST1R | c.3582C>T p.R1194= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as rs745538801, COSV56571312; called by muse, mutect2, varscan2
- MYH8 | c.2670G>A p.L890= | Silent (SNP) | VAF 43/97 reads (44%) | catalogued as rs748345785, COSV67969049; called by muse, mutect2, varscan2
- MYPN | c.2502G>A p.L834= | Silent (SNP) | VAF 50/114 reads (44%) | catalogued as COSV62736100; called by muse, mutect2, varscan2
- NCAPD3 | c.2496G>A p.E832= | Silent (SNP) | VAF 24/47 reads (51%) | catalogued as rs886657564, COSV73258519; called by muse, mutect2, varscan2
- NCKAP1L | c.435G>C p.L145= | Silent (SNP) | VAF 207/423 reads (49%) | catalogued as COSV53209720; called by muse, mutect2, varscan2
- NDST1 | c.1113C>T p.D371= | Silent (SNP) | VAF 13/36 reads (36%) | catalogued as rs139282708; called by muse, mutect2, varscan2
- OLR1 | c.270A>G p.Q90= | Silent (SNP) | VAF 77/285 reads (27%) | catalogued as COSV58872140; called by muse, mutect2, varscan2
- OR6N1 | c.784C>T p.L262= | Silent (SNP) | VAF 130/504 reads (26%) | catalogued as COSV58649590; called by muse, mutect2
- PABPC5 | c.9C>T p.S3= | Silent (SNP) | VAF 15/49 reads (31%) | catalogued as COSV57041561; called by muse, mutect2, varscan2
- PCDHGB1 | c.318C>T p.V106= | Silent (SNP) | VAF 62/135 reads (46%) | catalogued as COSV53989036; called by muse, mutect2, varscan2
- PHC2 | c.210G>A p.T70= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as rs372151966; called by muse, mutect2
- PIK3AP1 | c.30C>T p.C10= | Silent (SNP) | VAF 36/62 reads (58%) | catalogued as rs745891874, COSV59530543; called by muse, mutect2, varscan2
- PJVK | c.423C>T p.D141= | Silent (SNP) | VAF 22/49 reads (45%) | catalogued as COSV57869684; called by muse, mutect2, varscan2
- PKD1L1 | c.4974C>T p.G1658= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as COSV56971780; called by muse, mutect2, varscan2
- PLBD2 | c.1387C>A p.R463= | Silent (SNP) | VAF 49/114 reads (43%) | catalogued as COSV55106960, COSV55107940; called by muse, mutect2, varscan2
- PLS1 | c.1488A>G p.V496= | Silent (SNP) | VAF 12/75 reads (16%) | catalogued as rs1396669452, COSV61834707; called by muse, mutect2, varscan2
- PLXNA3 | c.1105C>T p.L369= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as COSV63754793; called by muse, mutect2, varscan2
- PNMA1 | c.696G>A p.A232= | Silent (SNP) | VAF 50/108 reads (46%) | catalogued as COSV54096857; called by muse, mutect2, varscan2
- PPL | c.4396C>T p.L1466= | Silent (SNP) | VAF 38/110 reads (35%) | catalogued as COSV52170363; called by muse, mutect2, varscan2
- PPP4R1 | c.2568C>T p.C856= (on ENST00000400556 / NM_001042388.3; = p.C839= on NM_005134.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 56/132 reads (42%) | catalogued as COSV53283175; called by muse, mutect2, varscan2
- PRKAB2 | c.192G>A p.Q64= | Silent (SNP) | VAF 134/281 reads (48%) | catalogued as COSV54214037; called by muse, mutect2, varscan2
- PTCD1 | c.1410C>G p.G470= | Silent (SNP) | VAF 19/47 reads (40%) | catalogued as COSV52865497; called by muse, mutect2, varscan2
- RBM5 | c.255C>T p.H85= | Silent (SNP) | VAF 86/243 reads (35%) | catalogued as rs144164147; called by muse, mutect2, varscan2
- RIPK4 | c.2233C>T p.L745= (on ENST00000352483; = p.L697= on NM_020639.3) | Silent (SNP) | VAF 10/42 reads (24%) | catalogued as rs1420002112, COSV60188729; called by muse, mutect2, varscan2
- RIPOR1 | c.207C>T p.A69= (on ENST00000379312 / NM_001193522.2; = p.A65= on NM_024519.4) | Silent (SNP) | VAF 39/72 reads (54%) | catalogued as rs1234982883, COSV50237791; called by muse, mutect2, varscan2
- RPSA | c.876T>C p.T292= | Silent (SNP) | VAF 25/60 reads (42%) | catalogued as COSV57191928; called by muse, mutect2, varscan2
- S100PBP | c.234T>C p.G78= | Silent (SNP) | VAF 18/316 reads (6%) | catalogued as COSV63140356; called by muse, mutect2
- S100PBP | c.1122C>T p.A374= | Silent (SNP) | VAF 34/89 reads (38%) | catalogued as COSV65110921; called by muse, mutect2, varscan2
- SART3 | c.36C>A p.P12= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV57208926; called by muse, mutect2
- SATB2 | c.1710C>T p.H570= | Silent (SNP) | VAF 17/131 reads (13%) | catalogued as rs764708410, COSV53479858, COSV53481127; called by muse, mutect2, varscan2
- SIRPB2 | c.18G>A p.S6= | Silent (SNP) | VAF 10/18 reads (56%) | catalogued as rs774750046, COSV63123964; called by muse, mutect2, varscan2
- SLC12A3 | c.144C>T p.S48= | Silent (SNP) | VAF 38/78 reads (49%) | catalogued as COSV52637039; called by muse, mutect2, varscan2
- SLC13A4 | c.1326C>T p.N442= | Silent (SNP) | VAF 46/107 reads (43%) | catalogued as rs1049436069, COSV62462020; called by muse, mutect2, varscan2
- SLC24A1 | c.822C>T p.S274= | Silent (SNP) | VAF 78/150 reads (52%) | catalogued as rs532760023, COSV56053039; called by muse, mutect2, varscan2
- SLC25A52 | c.573C>T p.F191= (on ENST00000672005; = p.F181= on NM_001034172.4) | Silent (SNP) | VAF 72/304 reads (24%) | catalogued as COSV52503295; called by muse, mutect2, varscan2
- SLC4A8 | c.2889C>T p.L963= | Silent (SNP) | VAF 91/196 reads (46%) | catalogued as rs141954048, COSV60655810; called by muse, mutect2, varscan2
- SPON1 | c.606C>T p.C202= | Silent (SNP) | VAF 28/85 reads (33%) | catalogued as rs782016066, COSV59964332; called by muse, mutect2, varscan2
- SPSB1 | c.357G>A p.T119= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV60164020; called by muse, mutect2, varscan2
- ST8SIA6 | c.621C>T p.S207= | Silent (SNP) | VAF 40/132 reads (30%) | catalogued as rs754645226, COSV101112219, COSV66465814; called by muse, mutect2, varscan2
- SYNGR4 | c.393G>A p.S131= | Silent (SNP) | VAF 35/71 reads (49%) | catalogued as COSV61225656; called by muse, mutect2, varscan2
- TECTA | c.4245C>T p.N1415= | Silent (SNP) | VAF 12/73 reads (16%) | catalogued as COSV50687776; called by muse, mutect2, varscan2
- TMCC2 | c.2112C>T p.H704= | Silent (SNP) | VAF 16/46 reads (35%) | catalogued as rs761567843, COSV58005114; called by muse, mutect2, varscan2
- TNKS1BP1 | c.159G>A p.L53= | Silent (SNP) | VAF 14/24 reads (58%) | catalogued as COSV64101803; called by muse, mutect2, varscan2
- TNN | c.3750G>A p.K1250= | Silent (SNP) | VAF 27/147 reads (18%) | catalogued as rs1421786250, COSV53430690; called by muse, mutect2, varscan2
- TPP2 | c.3741C>T p.C1247= | Silent (SNP) | VAF 18/188 reads (10%) | catalogued as rs771127079, COSV65753637; called by muse, mutect2, varscan2
- TRBV30 | c.270G>A p.Q90= | Silent (SNP) | VAF 7/26 reads (27%) | called by muse, mutect2, varscan2
- TRPM8 | c.213C>T p.G71= | Silent (SNP) | VAF 81/165 reads (49%) | catalogued as COSV61222957; called by muse, mutect2, varscan2
- TTC17 | c.960C>T p.H320= | Silent (SNP) | VAF 59/130 reads (45%) | catalogued as rs779419834, COSV50013064; called by muse, mutect2, varscan2
- TUBB2A | c.1260C>A p.S420= | Silent (SNP) | VAF 39/87 reads (45%) | catalogued as COSV61319320; called by muse, mutect2, varscan2
- UGGT1 | c.2640C>T p.C880= | Silent (SNP) | VAF 26/51 reads (51%) | catalogued as rs749149781, COSV52138719; called by muse, mutect2, varscan2
- USP24 | c.5907C>T p.G1969= | Silent (SNP) | VAF 5/70 reads (7%) | catalogued as COSV53772975; called by muse, mutect2
- ZC3H12D | c.624C>T p.P208= | Silent (SNP) | VAF 16/33 reads (48%) | catalogued as COSV66324786; called by muse, mutect2, varscan2
- ZFAND2B | c.135A>T p.G45= | Silent (SNP) | VAF 28/72 reads (39%) | catalogued as COSV54698241; called by muse, mutect2, varscan2
- ZFP41 | c.495C>T p.H165= | Silent (SNP) | VAF 46/108 reads (43%) | catalogued as COSV58087745; called by muse, mutect2, varscan2
- ZNF836 | c.999T>C p.N333= | Silent (SNP) | VAF 48/128 reads (38%) | catalogued as rs779415678, COSV59084725; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73852011 del A | 3'Flank (DEL) | VAF 42/68 reads (62%) | catalogued as rs200290800; called by mutect2, varscan2
- AP000769.3 | chr11:65502034 C>T | 5'Flank (SNP) | VAF 8/63 reads (13%) | catalogued as rs749666501; called by muse, varscan2
- ASIC3 | c.*45A>G | 3'UTR (SNP) | VAF 21/149 reads (14%) | catalogued as COSV52524429; called by muse, mutect2, varscan2
- BNIP1 | c.178-2760_178-2714delinsAGCCAGTTCTCTATCAAAGGGCATTTATTTGGACTGCTTCCACA | Intron (DEL) | VAF 12/127 reads (9%) | called by pindel, varscan2*
- C9orf129 | n.581G>A | RNA (SNP) | VAF 40/76 reads (53%) | catalogued as rs748098913, COSV64881881; called by muse, mutect2, varscan2
- CCDC140 | n.596C>T | RNA (SNP) | VAF 28/65 reads (43%) | catalogued as COSV54676298; called by muse, mutect2, varscan2
- FAM83A | c.*1775del | 3'UTR (DEL) | VAF 51/120 reads (43%) | called by mutect2, pindel, varscan2
- GP6 | c.*805del | 3'UTR (DEL) | VAF 7/37 reads (19%) | catalogued as rs1449880088; called by mutect2, pindel, varscan2
- INSIG1 | c.*15C>A | 3'UTR (SNP) | VAF 48/110 reads (44%) | catalogued as COSV60920795; called by muse, mutect2, varscan2
- KNOP1P1 | n.412C>T | RNA (SNP) | VAF 101/359 reads (28%) | called by muse, mutect2, varscan2
- LINC02870 | n.295G>T | RNA (SNP) | VAF 14/42 reads (33%) | called by muse, mutect2, varscan2
- MFSD4B | c.*186del | 3'UTR (DEL) | VAF 28/100 reads (28%) | catalogued as rs540972233; called by mutect2, varscan2
- P2RY4 | c.-3del | 5'UTR (DEL) | VAF 21/53 reads (40%) | called by mutect2, pindel, varscan2
- TP73-AS1 | n.1566G>A | RNA (SNP) | VAF 9/22 reads (41%) | called by muse, mutect2, varscan2
- VAX1 | chr10:117132236 G>A | 3'Flank (SNP) | VAF 13/32 reads (41%) | catalogued as rs776057410, COSV53329898; called by muse, mutect2, varscan2
- ZFP36L1 | chr14:68796240 del G | 5'Flank (DEL) | VAF 41/105 reads (39%) | called by mutect2, pindel, varscan2
